Somatic mutation profile of tumor specimen TCGA-CR-7382-01A (aliquot TCGA-CR-7382-01A-11D-2129-08) from TCGA case TCGA-CR-7382, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.5 years (18,078 days).
Specimen TCGA-CR-7382-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95d78680-d559-43b2-b618-8e4751a0ba41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7382-10A (Blood Derived Normal), aliquot TCGA-CR-7382-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47a1f4da-9f05-4ece-a95b-9bd891f86650

The open-access MAF lists 77 somatic variants for this specimen: 63 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 54, Silent 14, Nonsense Mutation 6, Splice Region 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, mutect2
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 65/118 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 15/94 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519947, COSV59042211, COSV59042295; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF5 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV99346343; called by muse, mutect2, varscan2
- ANKRD12 | c.2319G>C p.E773D | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100042001; called by muse, mutect2
- ATCAY | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.112); catalogued as COSV100008985; called by muse, mutect2
- ATP9A | c.1560C>G p.D520E | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV100125564; called by muse, mutect2
- CACNA1B | c.6979C>T p.R2327W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765789569, COSV53142151; called by muse, mutect2, varscan2
- CACNA1E | c.2848G>T p.E950* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | catalogued as COSV100704946; called by muse, mutect2, varscan2
- CASP8 | c.908A>G p.D303G (on ENST00000432109 / NM_033355.3; = p.D320G on NM_001228.4) | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99629570, COSV99630812; called by muse, mutect2, varscan2
- CATSPERE | c.1708C>G p.L570V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100835351; called by muse, mutect2, varscan2
- CD1E | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as rs371931193, COSV63769863; called by muse, mutect2, varscan2
- CENPP | c.212G>C p.S71T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.188); catalogued as COSV100981404; called by muse, mutect2, varscan2
- CMYA5 | c.6016G>C p.E2006Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); catalogued as COSV101484319; called by muse, mutect2
- CSGALNACT2 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); catalogued as COSV100989846; called by muse, mutect2, varscan2
- CTCF | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1486997074, COSV99866509; called by muse, mutect2
- DBT | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100923619; called by muse, mutect2, varscan2
- DDB1 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 22/289 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57104645; called by muse, mutect2
- DDB1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV57100809; called by muse, mutect2
- DDX4 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61755806; called by muse, mutect2
- DOCK2 | c.4091G>A p.R1364H | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769663046, COSV56946543, COSV56987375; called by muse, mutect2
- DSEL | c.3551T>C p.I1184T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100026048; called by muse, mutect2, varscan2
- EMC1 | c.93T>C p.D31= | Splice Region (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100367528; called by muse, mutect2, varscan2
- EZH1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1260794915, COSV52853871; called by muse, mutect2
- FNBP1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs775380196, COSV63085585; called by muse, mutect2, varscan2
- FOCAD | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.237); catalogued as rs1433716282, COSV100620669; called by muse, mutect2, varscan2
- FSIP1 | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100618331; called by muse, mutect2
- GALNT12 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100899185; called by muse, mutect2
- HERC1 | c.10661G>A p.R3554Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs766536918, COSV101496854; called by muse, mutect2, varscan2
- HGFAC | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs200907783; called by muse, mutect2, varscan2
- HK3 | c.1695C>G p.I565M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as rs1458876291, COSV99459248; called by muse, mutect2, varscan2
- IGLV3-19 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1269509306; called by muse, mutect2, varscan2
- MFN1 | c.366A>C p.K122N | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV99764684; called by muse, mutect2, varscan2
- MYH4 | c.3910C>T p.Q1304* | Nonsense Mutation (SNP) | VAF 22/139 reads (16%) | catalogued as COSV55121899; called by muse, mutect2, varscan2
- MYO3A | c.4046C>A p.A1349E | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99781337; called by mutect2, varscan2
- MYO7B | c.5026C>T p.R1676W | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs758438016, COSV67348621; called by muse, mutect2, varscan2
- NID1 | c.2507G>A p.G836D | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99938234; called by muse, mutect2
- NLRP5 | c.2239G>C p.D747H | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV101173861; called by muse, mutect2
- OR6M1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100484174; called by muse, mutect2, varscan2
- PCDHGB7 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV99545963; called by muse, mutect2
- PKP4 | c.3308G>C p.R1103T | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100733971, COSV99048560; called by muse, mutect2, varscan2
- PLEKHG4 | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100431196; called by muse, mutect2, varscan2
- PRMT7 | c.1329C>G p.F443L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100267227, COSV59832105; called by muse, mutect2
- PRUNE2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs764771986, COSV65027470; called by muse, mutect2
- PSMB4 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs748519387, COSV99305239; called by muse, mutect2, varscan2
- PUS7L | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs774965646, COSV100786594; called by muse, mutect2
- RHBDL1 | c.670C>A p.Q224K (on ENST00000219551 / NM_001318733.2; = p.Q159K on NM_001278720.2) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV99555969; called by muse, mutect2
- RYR2 | c.13987C>T p.R4663* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as rs1398653043, COSV100772582; called by muse, mutect2
- SCLT1 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 8/113 reads (7%) | catalogued as COSV99828455; called by muse, mutect2
- SEC23B | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV99358062; called by muse, mutect2
- SEC23IP | c.2308G>A p.G770R | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760151239, COSV64833080; called by muse, mutect2, varscan2
- SEMA3E | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 21/158 reads (13%) | catalogued as rs1350303800, COSV100319493; called by muse, mutect2, varscan2
- SKOR1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100408591; called by muse, mutect2
- SORCS2 | c.2642T>C p.V881A | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100213785; called by muse, mutect2, varscan2
- STAT5B | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99511292; called by muse, mutect2, varscan2
- TMEM37 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs141678483; called by muse, mutect2, varscan2
- TRAPPC6A | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs377546640; called by mutect2, varscan2
- TRIM71 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101070492; called by muse, mutect2, varscan2
- ZKSCAN5 | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as COSV100460353, COSV58741961; called by muse, mutect2, varscan2
- ZNF362 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1389529486, COSV100987047; called by muse, mutect2
- ZNF407 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.533); catalogued as COSV99996618; called by muse, mutect2
- ZNF594 | c.1747C>G p.L583V | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV101280562; called by muse, mutect2
- MDN1 | c.3211dup p.R1071Pfs*20 | Frame Shift Ins (INS) | VAF 5/55 reads (9%) | called by mutect2, pindel, varscan2
- CACNA1A | c.2001C>T p.G667= | Silent (SNP) | VAF 20/199 reads (10%) | catalogued as rs373695561; called by muse, mutect2
- CCDC28A | c.231C>T p.S77= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs1233184881, COSV100236619; called by muse, mutect2, varscan2
- EPB41L3 | c.66G>A p.A22= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1325389044; called by muse, mutect2
- FAM107A | c.45G>C p.L15= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV100723906; called by muse, mutect2, varscan2
- HNRNPM | c.2022C>T p.N674= | Silent (SNP) | VAF 19/177 reads (11%) | catalogued as rs753706820, COSV55313020; called by muse, mutect2, varscan2
- MROH2B | c.3567G>A p.V1189= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV101270677, COSV68188906; called by muse, mutect2
- PLIN3 | c.684G>A p.Q228= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99701700; called by muse, mutect2, varscan2
- RHBDL1 | c.669G>A p.L223= (on ENST00000219551 / NM_001318733.2; = p.L158= on NM_001278720.2) | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV99555967; called by muse, mutect2
- RHOBTB1 | c.855C>T p.L285= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs750986518, COSV61957870, COSV61958367; called by muse, mutect2, varscan2
- SCLT1 | c.1572G>A p.R524= | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as COSV99828454; called by muse, mutect2
- SMAD4 | c.138G>A p.K46= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as rs1555685022, COSV100748200; ClinVar: likely benign; called by muse, mutect2
- TENM2 | c.7608C>G p.A2536= (on ENST00000518659 / NM_001122679.2; = p.A2297= on NM_001080428.3) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV101319387; called by mutect2, varscan2
- TRAPPC9 | c.3234C>T p.H1078= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs373077080; called by muse, varscan2
- XPO7 | c.1479G>A p.L493= | Silent (SNP) | VAF 44/201 reads (22%) | catalogued as COSV99381976; called by muse, mutect2, varscan2
